Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A13P, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A13P-01A (Primary Tumor).

[page 1 of 2]
Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Other Related Data:

Billing Type:

INPATIENT

Financial Number:

Clinical Diagnosis & History:

Patient with papillary ca of thyroid.

ICD-0-3

Carcinoma, papillary w/
follicular variant

Specimens Submitted:

1: SP: Total thyroid gland

8340/3

Site: Thyroid, NOS C23.9 11/18/10

DIAGNOSIS:

- 1) THYROID; TOTAL THYROIDECTOMY;
- PAPILLARY CARCINOMA OF THYROID,, CLASSICAL TYPE AND FOLLICULAR VARIANT, WELL DIFFERENTIATED. MITOTIC ACTIVITY IS NIL. NO TUMOR NECROSIS IS IDENTIFIED. THE TUMOR INVOLVES THE RIGHT LOBE. THE TUMOR GREATEST DIAMETER IS 1.5 CM. THE TUMOR FOCALLY PENETRATES THE ADJACENT SOFT TISSUE. NO EVIDENCE OF BLOOD VESSEL INVASION IS IDENTIFIED. ALL SURGICAL MARGINS ARE FREE OF TUMOR. SINGLE FOCUS OF PAPILLARY MICROCARCINOMA IN THE LEFT LOBE. MICROSCOPIC MULTICENTRIC FOCI OF CARCINOMA ARE PRESENT. THE NON-NEOPLASTIC THYROID SHOWS NO ABNORMALITIES. NO PARATHYROID GLANDS ARE IDENTIFIED.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLICES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out

Gross Description:

- 1) The specimen is received fresh, labeled "Total thyroid gland". It consists of the entire thyroid with the right lobe measuring 5.0 x 2.0 x 1.5 cm, left lobe 3.5 x 1.7 x 1.0 cm with isthmus measuring 2.0 x 1.5 x 0.7 cm. The specimen is serially sectioned and the cut surfaces show a well-circumscribed, tan, firm, spherical mass measuring 1.5 cm in diameter, located in the inferior pole of the right lobe close to the right isthmus. The mass approaches closely, but does not involve the inked surface of the specimen. The specimen is submitted in

[page 2 of 2]
Summary of Sections:

RL - right lobe from superior pole to right isthmus

LL - left lobe from superior pole to left isthmus

Summary of Sections:

Part	Sect.	Site	Blocks	Pieces	All
1	ll		8	M	Y
	rl		9	M	

Source: NCI Genomic Data Commons file 1644c0ef-2734-4238-930a-4b38c2bd67bd (TCGA-DJ-A13P.3F98A8C0-C41C-4AA2-BBBC-2EA56B3EFBBD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).